Surgical pathology report (de-identified scan), TCGA case TCGA-AA-A00L, project TCGA-COAD (Colon Adenocarcinoma), tissue source site Indivumed, specimen TCGA-AA-A00L-01A (Primary Tumor).

Sample ID #:

Diagnosis:

Resectate of the colon (transverse colon) with inclusion of an ulcerated, moderately differentiated adenocarcinoma, of a maximum diameter of 6 cm, with infiltration of all layers of the wall, focally into the pericolic fatty tissue. Tumor-free resection margins, tumor-free omental fat tissue and tumor-free lymph nodes.

Tumor classification: G2, pT3 N0 (0/32) L0 V0; R0

ICD-O-3

adenocarcinoma, NOS 8140/3

Site: transverse colon C18.4 for 3/30/11

Crite-ia	Yes	No

Source: NCI Genomic Data Commons file 837bab69-3ace-42be-b89d-20a42d04a03d (TCGA-AA-A00L.3A6D9A07-C421-4C87-AC68-2A6FC3BFD05D.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).